CPTAC case C3L-02163 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0449aa40-ee66-45c5-baa7-db48dbcc7702

Demographics
Sex at birth: male; Race: white; Year of birth: 1960; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 57.5 years (21,020 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 727 days (2.0 years); Progression or recurrence: no; Days to last follow up: 727 days (2.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 2.7 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 9; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Days to follow up: 340 days; Disease response: Tumor Free.
- Days to follow up: 727 days (2.0 years); Disease response: Tumor Free; ECOG performance status: 0.
- Days to follow up: 727 days (2.0 years); Disease response: Complete Response; ECOG performance status: 0.

Other clinical attributes
- Weight: 74 kg; Height: 160 cm; BMI: 28.91.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Cigarettes per day: 20; Tobacco smoking onset year: 1997; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 25.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02163-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 3 days; Initial weight: 227 mg; Time between clamping and freezing: 10 minutes; Time between excision and freezing: 2 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02163-21: Section location: Left lung; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample C3L-02163-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 3 days; Initial weight: 506 mg; Time between clamping and freezing: 14 minutes; Time between excision and freezing: 6 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02163-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 3 days; Method of sample procurement: Blood Draw.
